FM case AD6845 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/da84bc1b-687e-4aa8-8c53-e9ebf104851c

Male, 74.9 years: Adenosquamous carcinoma (ICD-O-3 8560/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
